Surgical pathology report (de-identified scan), TCGA case TCGA-RD-A8N9, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Peter MacCallum Cancer Center, specimen TCGA-RD-A8N9-01A (Primary Tumor).

[page 1 of 4]
(Specimen Collected:

Comment for Episode
HISTOPATHOLOGY REPORT

REQUEST DETAILS

Gastric adenoca. Total gastrectomy.

MACROSCOPIC DESCRIPTION

1. Specimen labelled total gastrectomy. A total gastrectomy specimen including stomach measuring 160mm in length and 100mm in diameter, distal oesophagus 10mm in length and 25mm diameter, proximal duodenum 10mm in length and 25mm diameter, and greater omentum 500x150x15mm. The stomach is opened along the greater curve, revealing an ill-defined, indurated plaque in the cardia, overlying the lesser curve, approximately 35x35mm. The tumour appears to cross the gastro-oesophageal junction, but is centred on the stomach. On sectioning, the wall is firm and pale. The serosal surface appears normal with no puckering identified. This lesion extends close to the proximal resection margin, but is well clear of the distal resection margin. A second lesion is identified in the body of the stomach, in the greater curvature, approximately 50mm from the gastro-oesophageal junction. This is a firm white nodule within submucosa, covered by apparently normal mucosa, measuring 10mm in diameter. The remainder of the gastric mucosa shows fine granularity, but is otherwise unremarkable. The oesophageal mucosa is pale grey and shiny, with no lesion identified. The duodenal mucosa is normal. Block 1.1 to 1.4 serial TS through the tumour over the lesser curve, including gastro-oesophageal junction and proximal resection margin, 1.5 further section tumour immediately adjacent to gastro-oesophageal junction, 1.6 distal resection margin, 1.7 separate nodule greater curve, 1.8 through to 1.13 are possible lymph nodes taken from the adjacent fat, 1.14 and 1.15 representative sections from adjacent omentum, 1.16 oesophagus immediately adjacent to stapled margin, 1.17 tumour with serosal surface, 1.18 serosal margin from lesser omentum over tumour, 1.19 further sections mural nodule greater curve, 1.20 - 1.23 lymph nodes from lesser curve, from proximal to distal, 1.24-1.25 lymph nodes from greater curve. See attached photograph for details.

2. Specimen labelled anastomotic donut (proximal). Segment of oesophageal wall measuring 12mm in diameter. Serially sectioned and all processed in 2.1

3. Specimen labelled anastomotic donut (distal). Segment of bowel wall measuring 20x15mm. Serially sectioned and all processed in 3.1.

4. Specimen labelled splenic artery lymphatic tissue. Fatty tissue measuring 30x15x10mm. Serially sectioned and all processed in 4.1 and 4.2.

5. Specimen labelled common hepatic artery lymph node. Fatty tissue measuring 40x30x10mm. Serially sectioned and all processed in 5.1 and 5.2.

MICROSCOPIC DESCRIPTION

1. Sections show a large, extensively ulcerated tumour centred in the proximal stomach, but crossing the gastro-oesophageal junction and extending into distal oesophagus. The tumour is a poorly differentiated adenocarcinoma, consisting predominantly of sheets of epithelioid cells with large, markedly atypical nuclei, vesicular chromatin, prominent nucleoli and moderately abundant pale eosinophilic cytoplasm. Some cells have a signet ring cell morphology. Immunohistochemical staining for E-cadherin has been performed; the tumour cells are negative for this marker. Very focally (1.4), the tumour shows glandular differentiation with irregular glands surrounded by desmoplastic stroma. There is an associated patchy, but focally dense lymphoplasmacytic infiltrate with lymphoid follicle formation. Adenocarcinoma invades through the muscularis propria of stomach and into lesser curve fat, but there is no involvement of serosal surface. The tumour extensively

ICD-O-3
Adenocarcinoma, diffuse 8/4/5/3
Site: Gastroesophageal junction C14.0
NOS 8/4/5/3
Anastomotic junction C16.1

[page 2 of 4]
dermines oesophageal squamous mucosa, and invades through the oesophageal wall and into adventitial fat, but is narrowly clear of the radial resection margin. However, there is tumour present at the oesophageal resection margin adjacent to the staple line, in the plane of submucosa. The distal resection margin is clear of tumour.

Foci of lymphovascular and perineural invasion are identified. There is metastatic carcinoma within two of thirty-one (31) lymph nodes retrieved from the lesser curve; ten lymph nodes from the greater curve show no evidence of malignancy. No extracapsular extension by tumour is seen.

The adjacent gastric mucosa shows moderately dense chronic gastritis with focal activity; Helicobacter bacteria are not identified. No intestinal metaplasia is seen, either within oesophageal or gastric mucosa. The oesophageal and duodenal mucosa is unremarkable. Within the gastric wall, there are two intramural nodules identified: The first of these (block 1.7) is a circumscribed nodule 15mm in diameter, composed of interlacing fascicles of spindled cells with elongate ovoid nuclei and moderately abundant pale cytoplasm, sometimes with perinuclear vacuolation. There is no necrosis and mitotic figures are infrequent (3 per 50 high-power fields). Immunostains show diffuse immunoreactivity of spindled cells for c-kit (CD117) and CD34, whilst stains for S100 protein, desmin and EMA are negative. This is a benign gastrointestinal stromal tumour (GIST), clear of resection margins. The second nodule is within submucosa and muscularis propria and measures 8mm diameter (block 1.5). This comprises interlacing fascicles of cytologically uniform spindled cells possessing elongate ovoid nuclei and moderately abundant eosinophilic, sometimes fibrillary cytoplasm. There is no cytologic atypia, no necrosis is seen and no mitotic figures are identified. Immunostains show diffuse immunoreactivity for desmin and smooth muscle actin, whilst the spindled cells are negative for S100 protein, CD34, c-kit (CD117) and EMA. The features are of a benign leiomyoma, and this lesion is clear of margins.

2. Sections show pieces of oesophageal wall lined by unremarkable squamous epithelium. No glandular mucosa, intestinal metaplasia or malignancy is identified.

3. Sections show pieces of small intestinal wall showing no evidence of malignancy.

4. Sections show adipose tissue. No lymph node parenchyma is identified and there is no evidence of malignancy.

5. Sections show two small lymph nodes within adipose tissue. There is no evidence of metastatic carcinoma or other malignancy.

SYNOPTIC REPORT - CARCINOMA OF OESOPHAGOGASTRIC JUNCTION

Specimen type: Total gastrectomy.

Tumour site: Junctional, Siewert type III.

Tumour type: Adenocarcinoma.

Tumour grade: Poorly differentiated.

Depth of invasion: Subserosa.

Margins: Tumour is present adjacent to the staple line at the proximal resection margin of the main specimen, but no tumour is seen within separately submitted tissue from the proximal donut. The distal margin is clear of tumour.

Lymphovascular invasion: Present.

Lymph nodes: Metastatic carcinoma within two of forty-three lymph nodes.

Other:

- Moderate chronic gastritis with mild activity; Helicobacter bacteria are not identified;
- No intestinal metaplasia identified, either within oesophagus or stomach;
- Gastro-intestinal stromal tumour (GIST) of stomach, 15mm diameter, clear of margins;
- Leiomyoma of stomach, 8mm diameter, clear of margins.

DIAGNOSIS

1-5. Total gastrectomy, proximal and distal donuts, and common

[page 3 of 4]
hepatic artery lymph node: Poorly differentiated adenocarcinoma of gastro-oesophageal junction (Siewert type III), invading to subserosa, clear of proximal and distal margins, with metastatic carcinoma in two of forty-three lymph nodes (pT2N1Mx); moderate chronic gastritis with mild activity, without intestinal metaplasia; gastric gastrointestinal stromal tumour (GIST) 15mm diameter, clear of margins; gastric leiomyoma, 8mm diameter, clear of margins.

Pw TSS, dx discrepancy from
status TCGA tumor to be
adenocarcinoma, diffuse type. BCR

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	adenocarcinoma, NOS	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	adenocarcinoma, diffuse type.	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Subtype not specified in path report	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Designated Pathologist has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 4e69c2c0-7069-454d-a0fe-10baa8af83ee (TCGA-RD-A8N9.9F93F8DF-0086-414D-9D93-122D60125026.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).